Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACG-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

1. Specimen:

Liver: 16.0 x 10.0 x 3.8 cm, unfixed

Gallbladder:

8.0 cm in length, 4.2 cm in diameter, 4.0 mm in wall thickness, unfixed

2. Tumor location: left

Tumor number: one

Tumor size: 3.3 x 3.2 x 2.8 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes (5 %)

6. Hemorrhage/peliosis: no

7. Portal vein invasion: yes

8. Bile duct invasion: no

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JAD 5/19/14

Gross photo present.

Blocks

RM, resection margin x 1

TB, T1-5, Tumor mass x 6

NB, A, non-tumorous lesion x 2

GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation IV/IV

The major differentiation IV/IV

1-2. Histologic type: trabecular, compact

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Cholangiocarcinoma: no

3. Combined hepatocellular and cholangiocarcinoma: no

4. Other tumor: no

5. Fibrous capsule formation: partial capsule

[page 2 of 3]
- 6. Capsular infiltration: yes
- 7. Septum formation: no
- 8. Surgical resection margin invasion: no, margin of the clearance (0.4 cm)
- 9. Serosal invasion: no
- 10. Portal vein invasion: yes
- 11. Bile duct invasion: no
- 12. Hepatic vein invasion: no
- 13. Hepatic artery invasion: no
- 14. Microvessel invasion: yes
- 15. Intrahepatic metastasis: yes
- 16. Multicentric occurrence: no

Non-tumor liver pathology

- 1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: micronodular
- 2. Dysplastic nodule: no
- 3. Ductal epithelial dysplasia: no
- 4. Other liver diseases: no

SPECIAL STAIN: Trichrome (positive (stage IV))

kidney, hepatitis associated nephropathy, membranous glomerulonephritis

NOT reported. Gross:

NOT reported. Gross:

NOT reported. Gross:

kidney, needle, hepatitis associated nephropathy

Stomach, antrum, scopic, chronic gastritis, H. pylori, associated, dysplasia, low grade

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

[page 3 of 3]
DIAGNOSIS:

Liver, left, hemihepatectomy:

Hepatocellular carcinoma, poorly differentiated

Gallbladder, cholecystectomy:

Chronic cholecystitis

NOTE: Recommend to order immunohistochemistry(hepatocyte, CK7, CD56) for block T1 and special stain (Mucicarmine).

<ADDENDUM>

IMMUNOHISTOCHEMISTRY: CD56 (-), Hepatocyte (+), CK7 (-)

SPECIAL STAIN: Mucicarmine (-)

Suggestion :

Source: NCI Genomic Data Commons file 8a940eba-bed8-47b7-89f2-62b943403ed1 (TCGA-DD-AACG.8B0FA2B9-F484-4D9C-AFAE-BDD90DA6A7A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).